Somatic mutation profile of tumor specimen TCGA-25-2042-01A (aliquot TCGA-25-2042-01A-01W-0799-08) from TCGA case TCGA-25-2042, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 60.6 years (22,127 days).
Specimen TCGA-25-2042-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78f68bf4-c749-4843-8eb9-fb00f6e91c36.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-25-2042-10A (Blood Derived Normal), aliquot TCGA-25-2042-10A-01W-0799-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33f60097-feb9-4feb-9bcf-7ed0fb0caeaf

The open-access MAF lists 92 somatic variants for this specimen: 66 protein-altering or splice-affecting, 22 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 22, Nonsense Mutation 10, Splice Region 2, Intron 2, Frame Shift Del 2, In Frame Del 1, Splice Site 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.672G>A p.E224= | Splice Region (SNP) | VAF 15/59 reads (25%) | catalogued as rs267605076, CS100446, COSV52678333, COSV52681634, COSV52721244; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA12 | c.7363C>G p.L2455V (on ENST00000272895 / NM_173076.3; = p.L2137V on NM_015657.3) | Missense Mutation (SNP) | VAF 36/243 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV55949528; called by muse, mutect2, varscan2
- ANK1 | c.1354G>T p.V452L | Missense Mutation (SNP) | VAF 32/1010 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV99227143; called by muse, mutect2
- ARHGAP31 | c.2921G>A p.S974N | Missense Mutation (SNP) | VAF 59/444 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV99957848; called by muse, varscan2
- ART1 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV99167276; called by muse, mutect2, varscan2
- ATP13A5 | c.507G>T p.L169F | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as rs1335607011, COSV100665817, COSV60866683; called by muse, mutect2, varscan2
- BECN1 | c.389C>A p.T130K | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); catalogued as COSV100831198; called by muse, mutect2
- BMX | c.937A>C p.K313Q | Missense Mutation (SNP) | VAF 55/177 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV59590253; called by muse, mutect2, varscan2
- CATSPER2 | c.92A>T p.H31L | Missense Mutation (SNP) | VAF 120/716 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as COSV58660229; called by muse, mutect2, varscan2
- CCDC80 | c.145G>T p.A49S | Missense Mutation (SNP) | VAF 15/255 reads (6%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV99245404; called by muse, mutect2
- CHD4 | c.4178G>T p.R1393L (on ENST00000357008 / NM_001363606.2; = p.R1406L on NM_001273.5) | Missense Mutation (SNP) | VAF 87/471 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV58895065, COSV58902416; called by muse, mutect2, varscan2
- COL11A1 | c.3976G>A p.A1326T | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.073); catalogued as rs758156598, COSV100618217; called by muse, mutect2, varscan2
- COL11A1 | c.990G>A p.E330= | Splice Region (SNP) | VAF 15/65 reads (23%) | catalogued as rs1382407581, COSV62173257; called by muse, mutect2, varscan2
- CPT1A | c.1888C>A p.L630M | Missense Mutation (SNP) | VAF 36/592 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.091); catalogued as COSV99681666; called by muse, mutect2
- CSF2RB | c.1541G>A p.W514* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as COSV53255564, COSV99454635; called by muse, varscan2
- CSN3 | c.280C>A p.P94T | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.796); catalogued as COSV100515410, COSV59244464; called by muse, mutect2
- DCBLD2 | c.1216T>C p.F406L | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV58787402; called by muse, mutect2, varscan2
- EIF3L | c.727C>A p.Q243K | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67739361; called by muse, mutect2, varscan2
- FAM234B | c.1318C>A p.Q440K | Missense Mutation (SNP) | VAF 44/643 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as COSV99546041; called by muse, mutect2
- FOXK1 | c.1799C>G p.T600R | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as rs750885684, COSV61064418; called by muse, mutect2, varscan2
- FREM2 | c.1450G>A p.V484M | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as COSV54828688; called by muse, mutect2, varscan2
- GNL1 | c.1399C>T p.P467S | Missense Mutation (SNP) | VAF 125/462 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1485374550, COSV64920694; called by muse, mutect2, varscan2
- GPR155 | c.1247C>G p.T416S | Missense Mutation (SNP) | VAF 29/249 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV55037384; called by muse, mutect2, varscan2
- GPR50 | c.499G>T p.G167C | Missense Mutation (SNP) | VAF 78/495 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54437022; called by muse, mutect2, varscan2
- HFE | c.405C>A p.Y135* | Nonsense Mutation (SNP) | VAF 18/174 reads (10%) | catalogued as COSV58512483; called by muse, mutect2, varscan2
- KCNH5 | c.2152G>T p.E718* | Nonsense Mutation (SNP) | VAF 17/314 reads (5%) | catalogued as COSV100528409, COSV59758130; called by muse, mutect2
- KLHL11 | c.1055C>A p.P352H | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV100044517; called by muse, mutect2
- MAMDC2 | c.17T>C p.V6A | Missense Mutation (SNP) | VAF 664/724 reads (92%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV65856518; called by mutect2, varscan2
- MAN2B2 | c.1085A>G p.Y362C | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as rs754128908, COSV53450655; called by muse, mutect2, varscan2
- MYO3B | c.1549G>T p.E517* | Nonsense Mutation (SNP) | VAF 20/164 reads (12%) | catalogued as COSV100512035; called by muse, mutect2
- NARF | c.712G>T p.E238* | Nonsense Mutation (SNP) | VAF 12/98 reads (12%) | catalogued as COSV59110530; called by muse, mutect2, varscan2
- NDRG2 | c.623C>A p.S208Y (on ENST00000298687 / NM_001354570.1; = p.S194Y on NM_016250.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV100069187, COSV53872034; called by muse, mutect2, varscan2
- NFKBIZ | c.1715G>A p.R572K | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs776150669, COSV58199414, COSV58202128; called by muse, mutect2, varscan2
- NIT2 | c.661C>T p.H221Y | Missense Mutation (SNP) | VAF 61/340 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as COSV67630000; called by muse, mutect2, varscan2
- OR51E2 | c.715A>G p.T239A | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV67806714; called by muse, mutect2, varscan2
- OR5R1 | c.696G>T p.Q232H | Missense Mutation (SNP) | VAF 105/287 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV56571488; called by muse, mutect2, varscan2
- PAK3 | c.394C>T p.Q132* (on ENST00000262836 / NM_001324328.2; = p.Q117* on NM_002578.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 52/431 reads (12%) | catalogued as COSV99458498; called by muse, mutect2, varscan2
- PIFO | c.371A>C p.K124T | Missense Mutation (SNP) | VAF 77/586 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.344); catalogued as COSV63863638; called by muse, mutect2, varscan2
- POLA1 | c.1514-1G>C p.X505_splice | Splice Site (SNP) | VAF 23/245 reads (9%) | catalogued as COSV100985833; called by muse, mutect2
- PTCHD4 | c.733C>G p.L245V | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0.103); catalogued as COSV59777928, COSV59792725; called by muse, mutect2, varscan2
- RBM44 | c.803T>C p.V268A (on ENST00000611254; = p.V902A on NM_001080504.2) | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs762980720, COSV57627267; called by muse, mutect2, varscan2
- RFTN1 | c.1466G>T p.G489V | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV61916853; called by muse, mutect2
- SAG | c.616C>A p.P206T | Missense Mutation (SNP) | VAF 62/230 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.887); catalogued as rs749426098, COSV68590330; called by muse, varscan2
- SBF2 | c.73G>A p.G25R | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99816036; called by muse, mutect2, varscan2
- SEPHS1 | c.1033T>A p.Y345N | Missense Mutation (SNP) | VAF 149/877 reads (17%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.522); catalogued as COSV100526058; called by muse, mutect2, varscan2
- SLC35G2 | c.200_214del p.A67_M72delinsV | In Frame Del (DEL) | VAF 51/215 reads (24%) | catalogued as COSV67587794; called by mutect2, pindel, varscan2
- SLC40A1 | c.582G>C p.Q194H | Missense Mutation (SNP) | VAF 54/315 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776292203, COSV53721880; called by muse, mutect2, varscan2
- SPRYD4 | c.484C>A p.L162M | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57665203, COSV57665969; called by muse, mutect2, varscan2
- STARD13 | c.833C>T p.S278F (on ENST00000336934 / NM_001243476.3; = p.S160F on NM_052851.3) | Missense Mutation (SNP) | VAF 44/315 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as COSV99716454; called by muse, mutect2, varscan2
- STK36 | c.1903C>T p.H635Y | Missense Mutation (SNP) | VAF 31/478 reads (6%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.622); catalogued as COSV99832015; called by muse, mutect2
- SYNM | c.3352G>C p.E1118Q | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50440678; called by muse, mutect2, varscan2
- TECTA | c.4144G>A p.V1382M | Missense Mutation (SNP) | VAF 116/362 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.119); catalogued as rs199637730, COSV50689122; called by muse, mutect2, varscan2
- TEX44 | c.217G>T p.V73F | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.423); catalogued as COSV58354609; called by muse, mutect2, varscan2
- TMEM86A | c.367G>T p.V123L | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV55010028; called by muse, mutect2, varscan2
- TRIM5 | c.414C>A p.Y138* | Nonsense Mutation (SNP) | VAF 32/137 reads (23%) | catalogued as COSV59898668; called by muse, mutect2, varscan2
- TTN | c.12121G>T p.E4041* (on ENST00000591111; = p.E3995* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 45/370 reads (12%) | catalogued as COSV59893210; called by muse, mutect2, varscan2
- WDR75 | c.2228C>G p.S743C | Missense Mutation (SNP) | VAF 72/306 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV59104728; called by muse, mutect2, varscan2
- WNT2B | c.814G>T p.A272S (on ENST00000369684 / NM_024494.3; = p.A253S on NM_004185.4) | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as COSV56672522; called by muse, mutect2, varscan2
- WRN | c.631C>G p.L211V | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.114); catalogued as rs980659335, COSV53296188; called by muse, mutect2, varscan2
- ZBTB25 | c.207A>C p.Q69H | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67198362; called by muse, mutect2, varscan2
- ZNF551 | c.124G>T p.E42* | Nonsense Mutation (SNP) | VAF 63/1232 reads (5%) | catalogued as rs200132818, COSV56594934; called by muse, mutect2
- ZNF649 | c.1462G>C p.V488L | Missense Mutation (SNP) | VAF 46/564 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100031349; called by muse, mutect2
- ZRANB1 | c.1916A>G p.N639S | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs773977335, COSV58332595; called by muse, mutect2, varscan2
- LCAT | c.994_1040del p.G332Hfs*19 | Frame Shift Del (DEL) | VAF 68/98 reads (69%) | called by mutect2, pindel
- LEXM | c.998T>A p.L333* | Nonsense Mutation (SNP) | VAF 24/235 reads (10%) | called by mutect2, varscan2
- VCP | c.1943del p.P648Lfs*31 | Frame Shift Del (DEL) | VAF 30/114 reads (26%) | called by mutect2, pindel, varscan2
- ADAM18 | c.990T>C p.D330= | Silent (SNP) | VAF 31/231 reads (13%) | catalogued as rs1420380869, COSV55843889; called by muse, mutect2, varscan2
- CCDC141 | c.2538C>A p.S846= | Silent (SNP) | VAF 53/188 reads (28%) | catalogued as COSV55369035, COSV55372411; called by muse, mutect2, varscan2
- DYNC1H1 | c.3516T>C p.Y1172= | Silent (SNP) | VAF 109/431 reads (25%) | catalogued as rs1455284015, COSV64134446; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1749G>T p.L583= (on ENST00000361735 / NM_015935.5; = p.L497= on NM_014955.3) | Silent (SNP) | VAF 12/201 reads (6%) | catalogued as COSV100676074; called by muse, mutect2
- ELMO3 | c.1263G>T p.L421= (on ENST00000652269; = p.L368= on NM_024712.5) | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV62605887; called by muse, mutect2, varscan2
- FRMPD1 | c.4434A>G p.R1478= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs773939270; called by muse, varscan2
- HEYL | c.30C>T p.S10= | Silent (SNP) | VAF 18/20 reads (90%) | catalogued as rs1414797813, COSV65721356; called by muse, mutect2, varscan2
- HYAL3 | c.282C>A p.G94= | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as COSV56496781; called by muse, mutect2, varscan2
- IGDCC3 | c.1131G>A p.R377= | Silent (SNP) | VAF 12/109 reads (11%) | catalogued as COSV60076508; called by muse, mutect2, varscan2
- MOB2 | c.522G>A p.T174= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs776790913, COSV57317889; called by muse, mutect2, varscan2
- MOV10L1 | c.195G>T p.V65= | Silent (SNP) | VAF 70/510 reads (14%) | catalogued as COSV99435425; called by muse, mutect2, varscan2
- PCDHGA10 | c.2046C>T p.F682= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV53921657; called by mutect2, varscan2
- PIK3C2G | c.423C>T p.F141= | Silent (SNP) | VAF 35/68 reads (51%) | catalogued as COSV56812624, COSV99854319; called by muse, mutect2, varscan2
- RABGAP1 | c.300C>G p.L100= | Silent (SNP) | VAF 32/153 reads (21%) | catalogued as rs376306008, COSV58059688; called by muse, mutect2, varscan2
- SLC28A2 | c.1737C>A p.A579= | Silent (SNP) | VAF 40/800 reads (5%) | catalogued as COSV100754838; called by muse, mutect2
- SLCO1B3 | c.1290C>T p.C430= | Silent (SNP) | VAF 14/119 reads (12%) | catalogued as rs369799686, COSV53932621; called by muse, mutect2, varscan2
- TAF3 | c.1695C>T p.D565= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as COSV60203310; called by muse, mutect2, varscan2
- TRPA1 | c.2844C>T p.V948= | Silent (SNP) | VAF 22/154 reads (14%) | called by mutect2, varscan2
- TXNRD2 | c.249C>T p.G83= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs375701461; called by muse, mutect2, varscan2
- VCAM1 | c.1689T>G p.T563= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV99658992; called by muse, mutect2, varscan2
- VWA5A | c.690C>G p.L230= | Silent (SNP) | VAF 122/372 reads (33%) | catalogued as COSV100795679, COSV63707174; called by muse, mutect2, varscan2
- YJU2 | c.231C>T p.Y77= | Silent (SNP) | VAF 132/283 reads (47%) | catalogued as rs773145315, COSV53605395; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73825985 C>G | 5'Flank (SNP) | VAF 153/571 reads (27%) | called by muse, mutect2, varscan2
- MIR424 | n.30G>T | RNA (SNP) | VAF 5/54 reads (9%) | called by muse, mutect2
- MRPL3 | c.630-7868C>G | Intron (SNP) | VAF 34/93 reads (37%) | catalogued as COSV99395104; called by muse, mutect2, varscan2
- NACA | c.70+3062C>A | Intron (SNP) | VAF 21/94 reads (22%) | catalogued as rs766700608, COSV63267441; called by muse, mutect2, varscan2
